HCMI case HCM-CSHL-0864-C44 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d2de259e-d8bb-40ae-a155-c288e016fee6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C44.529; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 77.0 years (28,135 days); Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 240 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease.
2. Squamous cell carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8070/6; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Thorax, NOS; Classification of tumor: metastasis; Age at diagnosis: 77.6 years (28,331 days); Days to diagnosis: 196 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Maintenance Therapy; Days to treatment start: 30 days; Treatment outcome: Stable Disease.

Follow-up (2 entries)
- Days to follow up: 450 days (1.2 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 319.

Molecular and laboratory tests
- MLH1 hypermethylation: Equivocal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65.3 kg; Height: 177.8 cm; BMI: 21.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-CSHL-0864-C44-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0864-C44-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
